Gene-level copy-number profile of tumor specimen C3L-07147-01 from CPTAC case C3L-07147, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 76.9 years (28,102 days).
Specimen C3L-07147-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a1eb2d12-ca2c-4ab6-b70c-48d7db903e3b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-07147-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/5ac1cd17-3477-4e1c-88cd-c94cf7fd62eb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 83; copy number 1: 14,531; copy number 2: 28,927; copy number 3: 11,628; copy number 4: 1,611; copy number 5: 1,083; copy number 6: 182; copy number 7: 277; copy number 8: 51; copy number 9: 8; copy number 10: 2; copy number 26: 2; copy number 41: 1.

Homozygous deletions (total copy number 0; autosomes only): 83 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr7:56,991,888–57,020,273, 2 genes: TNRC18P3, SLC29A4P1.
- chr9:21,966,929–29,318,952, 64 genes (within-gene range 0–1) (broad region; genes not listed).
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.
- chr17:16,804,627–16,845,881, 5 genes: AC022596.1, NOS2P4, KRT16P6, KRT16P2, KRT17P1.
- chr18:41,819,053–41,819,421, 1 gene: AC011225.1.
- chr21:43,053,191–43,107,570, 2 genes: CBS, U2AF1.
- chr21:43,115,334–43,141,092, 2 genes: MRPL51P2, FRGCA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,606 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–675,265, 41 genes, copy number 5: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, WBP1LP6.
- chr1:149,054,027–150,353,233, 55 genes, copy number 5: NBPF9, AC239804.2, RNVU1-24, AC245297.3, AC245297.1, AC245297.2, 7SK, SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19, PPIAL4C, LINC00869, AC242842.2, AC242842.1, RNVU1-30, FAM91A2P, AC243772.3, RNU1-68P, AC243772.1, FCGR1A, H2BC18, AC243772.2, H3C13, H4C14, H3C14, H2AC18, H2BC19P, H2BC20P, H2AC19, H3C15, H4C15, AC239868.1, H2BC21, H2AC20, H2AC21, BOLA1, SV2A, SF3B4, MTMR11, OTUD7B, AC244033.2, AC244033.1, VPS45, PLEKHO1, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3.
- chr1:150,548,562–161,199,054, 541 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr1:182,641,816–183,928,532, 27 genes, copy number 5: RGS8, LINC01688, AL353778.1, NPL, AL355999.1, DHX9, SHCBP1L, HMGN1P4, 5S_rRNA, AL450304.1, KRT18P28, RNU6-41P, LAMC1, LAMC1-AS1, LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1, SMG7-AS1, SMG7, NCF2, ARPC5, RGL1, APOBEC4, AL157899.1, AL590422.1.
- chr1:184,790,724–184,974,508, 1 gene, copy number 5 (within-gene range 4–5): NIBAN1.
- chr1:184,999,710–185,291,781, 9 genes, copy number 5 (within-gene range 4–5): LINC01633, RNA5SP72, RNF2, FTH1P25, TRMT1L, SWT1, RPL22P24, RPL5P5, Y_RNA.
- chr1:188,671,353–189,133,292, 7 genes, copy number 5: AL929288.2, RPS3AP9, AL691515.1, AL691515.2, LINC01035, CLPTM1LP1, GAPDHP75.
- chr3:3,039,033–3,627,296, 7 genes, copy number 5–7 (within-gene range 4–7): CNTN4-AS1, IL5RA, AC024060.1, TRNT1, CRBN, AC024060.2, AC034195.1.
- chr3:4,493,345–7,741,533, 27 genes, copy number 5–7 (within-gene range 4–7): ITPR1, EGOT, AC018816.2, AC018816.1, BHLHE40-AS1, BHLHE40, RNF10P1, UBTFL8, Y_RNA, AC090955.1, ARL8B, AC026202.2, AC026202.3, EDEM1, MIR4790, RN7SL553P, AC026202.1, AC087857.1, AC026167.1, AC027119.1, AC069277.1, GRM7-AS3, AC069277.2, GRM7, MRPS36P1, GRM7-AS2, AC066585.1.
- chr3:7,606,890–11,039,247, 81 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr3:11,556,069–12,788,671, 27 genes, copy number 6–9 (within-gene range 2–9): VGLL4, AC022001.2, AC022001.3, TAMM41, FANCD2P2, CYCSP12, NUP210P2, MARK2P14, AC090958.1, RN7SL147P, SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17.
- chr3:75,906,695–77,649,964, 1 gene, copy number 8 (within-gene range 3–8): ROBO2.
- chr3:76,434,018–82,808,021, 36 genes, copy number 5–8: CAP1P1, RNU6-386P, VDAC1P7, AC133040.1, RNU6-217P, LINC02077, AC117462.1, RN7SL647P, RN7SKP61, AC108752.1, MRPS17P3, ROBO1, AC055731.1, RN7SL751P, AC117461.1, MIR3923, HMGB1P38, OSBPL9P1, HNRNPA3P8, AC108740.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1.
- chr7:91,264,433–92,401,383, 17 genes, copy number 5: FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1.
- chr7:93,424,486–93,574,730, 3 genes, copy number 5: CALCR, MIR653, MIR489.
- chr7:98,877,933–99,050,831, 1 gene, copy number 7 (within-gene range 3–7): TRRAP.
- chr7:98,989,867–100,968,347, 118 genes, copy number 5–7 (broad region; genes not listed).
- chr9:69,035,747–69,255,187, 1 gene, copy number 5 (within-gene range 3–5): AL358113.1.
- chr9:69,107,926–72,108,312, 37 genes, copy number 5: AL162730.1, TJP2, BANCR, FAM189A2, APBA1, AL355140.1, AL353693.1, AL162412.1, PTAR1, C9orf135-DT, C9orf135, RN7SL570P, MAMDC2-AS1, MAMDC2, RNU2-5P, SMC5-AS1, RPL24P8, SMC5, AL162390.1, Y_RNA, KLF9, TRPM3, RN7SL726P, AL159990.2, AL159990.1, MIR204, PIGUP1, RPL35AP21, CEMIP2, AL671309.1, ABHD17B, Y_RNA, C9orf85, HSPB1P1, C9orf57, AL583829.1, BTF3P4.
- chr9:92,711,363–92,764,833, 1 gene, copy number 6: BICD2.
- chr9:120,855,651–121,050,275, 3 genes, copy number 5: PHF19, TRAF1, C5.
- chr11:83,455,012–85,627,922, 1 gene, copy number 5 (within-gene range 2–9): DLG2.
- chr11:84,545,131–86,069,882, 21 genes, copy number 5 (within-gene range 5–9): HNRNPA1P72, AP000852.1, AP001825.1, AP001825.2, AP001825.3, AP000857.2, AP000857.1, HNRNPCP6, AP002803.1, AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM.
- chr11:86,283,927–86,672,636, 9 genes, copy number 6: AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3.
- chr12:12,326,056–12,357,067, 3 genes, copy number 5: MANSC1, RPL23AP66, LOH12CR2.
- chr12:12,927,726–33,982,566, 359 genes, copy number 5 (broad region; genes not listed).
- chr13:73,036,401–73,661,891, 10 genes, copy number 5: PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr13:77,697,687–77,844,145, 3 genes, copy number 5–7: SLAIN1, MIR3665, EDNRB-AS1.
- chr17:59,859,479–60,550,798, 34 genes, copy number 5: TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.4, AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.6, AC025048.3, AC025048.2, AC025048.5, AC025048.7, AC025048.1, CA4, USP32, SCARNA20, AC104763.1, AC104763.2, H3P42, C17orf64, RPL12P38, APPBP2, AC011921.3, AC011921.1.
- chr18:1,509,022–3,478,978, 41 genes, copy number 5 (within-gene range 3–5): AP005262.1, AC019183.1, AP005057.1, AP005230.1, AIDAP3, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2, SMCHD1, AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:13,726,660–14,010,917, 5 genes, copy number 10–41 (within-gene range 3–41): RNMT, MC5R, MC2R, AP001086.1, AC006557.6.
- chr19:27,638,483–28,313,500, 16 genes, copy number 5: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1.
- chr19:30,219,666–33,382,686, 63 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,943. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
